Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5H1, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5H1-01A (Primary Tumor).

[page 1 of 4]
Patient: [Redacted] Referring Physician: [Redacted]

Gender: F

Ref#: [Redacted] Hosp#: [Redacted] Patient Location: [Redacted]
Date of Service: [Redacted] Date Received: [Redacted]

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

RIGHT KIDNEY, RADICAL NEPHRECTOMY:

- CHROMOPHOBE RENAL CELL CARCINOMA, FUHRMAN GRADE 2.
- THE TUMOR IS 3.5 CM IN DIAMETER.
- TUMOR IS CONFINED WITHIN KIDNEY, ABUTS THE RENAL CAPSULE, AND IS PRESENT AT SUPERIOR POLE.
- VASCULAR AND URETERAL MARGINS FREE OF TUMOR.
- NEGATIVE FOR RENAL SINUS INVASION.
- ARTERIOLOSCLEROSIS IN NON-TUMOR PORTION OF KIDNEY, COMPATIBLE WITH PATIENT'S HISTORY OF HYPERTENSION.

COMMENT: This case has been reviewed by [Redacted] who concurs with the diagnosis of chromophobe renal cell carcinoma.

ICD-O-3

Carcinoma, renal cell
Chromophobe type 8317/3
Site: R Kidney NOS C64.9

Case # [Redacted]

[page 2 of 4]
Patient: [REDACTED]

Case #: [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Case #: [REDACTED]

Page 2
This report continues... (FINAL)

[page 3 of 4]
Patient: [REDACTED]

Case # [REDACTED]

Procedure:

Specimen type:

Specimen laterality:

Radical nephrectomy.

Kidney resection.

Right.

TUMOR FEATURES:

Tumor size:

Tumor focality:

Histologic type:

Histologic grade:

Sarcomatoid features:

Macroscopic extent of tumor:

Microscopic tumor extension:

3.5 cm.

Unifocal.

Chromophobe renal cell carcinoma.

2.

Absent.

Confined within kidney abutting renal capsule.

Confined within kidney, confined within renal capsule.

LYMPH NODES:

None identified.

MARGIN EVALUATION:

Distance to closest margin:

Tumor present at least 4.5 cm from vascular margin and ureteral margin.

PATHOLOGIC TUMOR STAGING:

Primary tumor:

Regional lymph nodes:

Distant metastasis:

Margin status:

Pathologic stage:

pT1a.

pNX.

pMX.

Negative (R0).

I.

Pathologic findings in non-neoplastic kidney:

Arteriosclerosis, scattered sclerotic glomeruli,
nonspecific mild chronic inflammation.

Case #: [REDACTED]

[page 4 of 4]
Patient: [REDACTED]

Case #: [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Kidney; Right

Clinical History/Operative Dx:

Renal mass

Gross Description:

Single specimen received at this time designated as right kidney. Initially received in a fresh state for tumor bank studies, is a 598 gram radical nephrectomy with an abundant perinephric fat, 17.5 x 10.2 x 5.6 cm. The adrenal gland is not included. The ureter extends out to 8.0 cm and narrows to 0.3 cm in diameter with a pinpoint lumen. Initially a palpable mass is not appreciated, and the kidney is bisected, to reveal a well circumscribed, glistening pale tan tumor mass near the upper pole, measuring 3.5 x 3.0 x 2.6 cm. This tumor abuts the anterior and posterior renal capsules. Anteriorly the Gerota's fascia overlies the perinephric fat which extends out to 0.7 cm from the tumor mass (A4, A5), and the posterior fat extends out to 0.6 cm (A6). The mass lesion approaches to within 0.1 cm of the fatty sinuses. A representative portion of tumor is submitted for tumor bank studies. The renal vessels extend down 2.5 cm, with the margins greater than 4.5 cm from the tumor mass. The pelvis is 3.0 x 1.8 cm, with glistening light tan mucosa, without grossly invasive tumor. The cut sections of the kidney demonstrate a distinct cortical medullary demarcation with grossly normal red-tan parenchyma without additional nodularity. The hilar fat has no gross tumor involvement and no grossly distinct lymph node tissue candidates. Representative sections are submitted.

Cassette summary: A1) ureter and renal vascular margins, A2) posterior and anterior renal pelvis represented, A3-A5) representation of tumor, renal capsule, Gerota's fascia, A6) tumor, posterior renal capsule and overlying fat, A7) tumor, adjacent renal sinus, A8) uninvolved kidney represented. [REDACTED]

Microscopic Description:

Immunohistochemical stains: Tumor cells positive for CK7, CD117, PAX-8 and CD10. Tumor cells negative for Vimentin. The morphologic and immunohistochemical findings are compatible with diagnosis of chromophobe renal cell carcinoma. Appropriate positive and negative immunohistochemical controls have been reviewed.

Case #: [REDACTED]

Page 4

REPRINT: Orig. printing on

move to chromophobe		12/18/12	Yes	No
Criteria				

Source: NCI Genomic Data Commons file 8a78eedc-6b33-42fb-975d-5306a42f389f (TCGA-NP-A5H1.6B36ACD0-3F89-4240-8A34-9765FA673403.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).